Gene-level copy-number profile of tumor specimen HCM-BROD-0695-C71-02B from HCMI case HCM-BROD-0695-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.3 years (21,646 days).
Specimen HCM-BROD-0695-C71-02B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8b7eeb7d-d6e5-4122-b2e1-c55fd1f22a4e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0695-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/ef8af42a-75dd-4728-b1ae-c8e2a0e8a5e8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 446; copy number 1: 438; copy number 2: 5,637; copy number 3: 6,830; copy number 4: 39,654; copy number 5: 3,158; copy number 6: 2,560; copy number 7: 125; copy number 8: 28; copy number 9: 12; copy number 11: 1; copy number 133: 7; copy number 142: 10.

Homozygous deletions (total copy number 0; autosomes only): 132 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:60,281,444–60,546,660, 1 gene: AC244258.1.
- chr10:34,815,767–34,966,259, 5 genes: PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2.
- chr10:42,185,339–42,276,842, 3 genes: IGKV1OR10-1, AL031601.1, AL031601.2.
- chr10:116,590,385–116,609,175, 1 gene: PNLIPRP1.
- chr14:18,333,726–19,691,194, 67 genes (broad region; genes not listed).
- chr21:7,744,962–9,129,752, 42 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:10,397,644–13,120,807, 13 genes: AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 30 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,330,670–55,433,742, 17 genes, copy number 133–142: LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr7:155,611,231–155,645,205, 1 gene, copy number 11 (within-gene range 8–11): AC009403.1.
- chr16:53,055,033–53,329,150, 5 genes, copy number 9: CHD9, AC007906.1, AC079416.4, AC079416.2, AC079416.3.
- chr17:82,031,678–82,065,887, 7 genes, copy number 9: RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L.

Autosomal genes at a single copy (total copy number 1): 175. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
